Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A6BL, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A6BL-01A (Primary Tumor).

[page 1 of 2]
THIS IS A CONFIDENTIAL AND PRIVILEGED COMMUNICATION
PLEASE DISPOSE OF PAPER COPIES APPROPRIATELY

Printed by:

Name: [REDACTED]
Test Name: PLEURA RT.{7TH RIB{PLEURA RT.
Ordered By:

Age:
Test Date:

COLLECTION DATE:
SPECIMEN NUMBER: [REDACTED]

SPECIMENS:
1. PLEURA RT.
2. 7TH RIB
3. PLEURA RT.

IED-0-3
Mesothelioma, biphasic,
malignant 9053/13
Date Pleura NOS C38.4
QWS/16/13

DIAGNOSIS:

1. PLEURA, RIGHT: BIOPSY
- DIFFUSE MALIGNANT MESOTHELIOMA, BIPHASIC TYPE (MIXED EPITHELIAL AND SARCOMATOID TYPE). SEE COMMENT.
2. RIB, SEVENTH: EXCISION
- UNREMARKABLE RIB.
3. PLEURA, RIGHT: BIOPSY
- DIFFUSE MALIGNANT MESOTHELIOMA, BIPHASIC TYPE (MIXED EPITHELIAL AND SARCOMATOID TYPE). SEE COMMENT.

Comment: Immunohistochemical stains are positive for calretinin and negative for TTF-1 and CD34. CK 5/6 is negative. The morphology and immunohistochemical findings support the above diagnoses. The case has been reviewed within the department.

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:
Rule out mesothelioma.

MACROSCOPIC DESCRIPTION:
The specimen is received fresh in three parts each labeled with the patient's name.

1. Part one is received fresh for intraoperative consultation labeled 'pleura right'. It consists of a 1 x 0.5 x 0.3 cm piece of tan soft tissue. The pleural surface is identified, which is black and focally nodular. The specimen is bisected and entirely submitted for frozen section.
2. Part two is labeled '7th rib'. It consists of a 7 x 1.5 x 0.5 cm portion of unremarkable rib. Representative tissue is submitted after decalcification.

HRAS Discrepancy		☒

[page 2 of 2]
3. Part three is labeled 'pleura right'. It consists of two pieces of firm soft tissue (1.5 x 1 x 0.5 cm and 1 x 0.4 x 0.2 cm). The pleural surface appears thickened. The specimen is entirely submitted.

SUMMARY OF SECTIONS:

1A frozen section control

2A representative rib

3A larger piece

3B smaller piece

SPECIAL PROCEDURES:

Calretinin, CK5/6, TTF-1, CD34

INTRA - OPERATIVE CONSULTATION:

1. Pleura, right, lesion; biopsy (frozen section)

- Atypical spindle and epithelioid proliferation with inflammation, favor mesothelioma, to be further studied in permanent sections.

Diagnosis read back by Dr. at

Intra-Operative Consultation #1 performed by

Electronically signed

Final Diagnosis performed by

Electronically signed

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 6c8ce058-2b7a-4e2d-aaf5-74fd965814d3 (TCGA-MQ-A6BL.C2E205E9-C239-49A6-B725-0785545207B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).